Somatic mutation profile of tumor specimen TCGA-NK-A5CT-01A (aliquot TCGA-NK-A5CT-01A-31D-A26M-08) from TCGA case TCGA-NK-A5CT, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.4 years (25,726 days).
Specimen TCGA-NK-A5CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70098c84-b492-4337-87bb-4161a5a93b93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NK-A5CT-10A (Blood Derived Normal), aliquot TCGA-NK-A5CT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eaf6e1e-60c6-41c1-a0fe-8ac4baba5b6b

The open-access MAF lists 370 somatic variants for this specimen: 279 protein-altering or splice-affecting, 85 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 85, Nonsense Mutation 16, Frame Shift Del 9, Splice Region 5, Intron 4, Frame Shift Ins 2, Splice Site 2, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906659, CM118819, COSV60907479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 26/75 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100228648, COSV99079207; called by muse, mutect2, varscan2
- ACKR4 | c.89T>G p.I30S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99391749; called by muse, mutect2, varscan2
- ACTR1B | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100007965, COSV100008031; called by muse, mutect2
- ACTR1B | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100008032; called by muse, mutect2
- ACTR6 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99498532; called by muse, mutect2, varscan2
- ACVR1B | c.1378T>G p.W460G | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231323; called by muse, mutect2
- ADAM9 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs763594099, COSV101166011, COSV65962467; called by muse, varscan2
- ADAMTSL1 | c.5089G>T p.A1697S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV101000838; called by muse, varscan2
- ADTRP | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99995115; called by muse, mutect2, varscan2
- ALDH1A2 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs763114869, COSV99990525; called by muse, mutect2, varscan2
- ANKRD13C | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs775485313, COSV99256447; called by muse, mutect2, varscan2
- ANKZF1 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99850356; called by muse, mutect2, varscan2
- AP2A1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99883040; called by muse, mutect2
- ARF5 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99133659; called by muse, mutect2, varscan2
- ARGFX | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs200448128, COSV100544088; called by muse, mutect2, varscan2
- ARHGAP22 | c.2029A>G p.M677V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs148992704; called by muse, mutect2, varscan2
- ARHGEF11 | c.1407-2A>G p.X469_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100809844; called by muse, mutect2, varscan2
- ARID1A | c.4070A>T p.Q1357L | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV61387446; called by muse, mutect2, varscan2
- ARID4B | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV99935216; called by muse, mutect2, varscan2
- ASH1L | c.2836G>C p.D946H | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1558149619, COSV100853227; called by muse, mutect2, varscan2
- ATG4C | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1348848518, COSV100507781; called by muse, mutect2, varscan2
- ATP1A4 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs773173259, COSV100927462, COSV100927539; called by muse, mutect2, varscan2
- ATP4A | c.2624C>A p.A875D | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99382295; called by muse, mutect2, varscan2
- ATP8B4 | c.2343G>T p.M781I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV99464348; called by muse, mutect2, varscan2
- B3GNT7 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs745834879, COSV99069843; called by muse, mutect2, varscan2
- BNC2 | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101032509, COSV66140742; called by muse, mutect2, varscan2
- BOLL | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99986931; called by muse, mutect2, varscan2
- BPIFB3 | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100972319; called by muse, mutect2, varscan2
- BRPF1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV100115199; called by muse, mutect2, varscan2
- C16orf78 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100147604; called by muse, varscan2
- C6orf15 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99456724; called by muse, mutect2, varscan2
- CA10 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as rs775450131, COSV53354863, COSV99562080; called by muse, mutect2, varscan2
- CADPS2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100461437; called by muse, mutect2, varscan2
- CCDC112 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201977366, COSV101100400; called by mutect2, varscan2
- CCDC136 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99922341; called by muse, mutect2, varscan2
- CCDC178 | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100283958; called by muse, mutect2, varscan2
- CD1D | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV100939566; called by muse, mutect2, varscan2
- CD5 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as rs1286665943, COSV100759769; called by muse, mutect2, varscan2
- CDC42BPA | c.2830A>G p.I944V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100504171; called by muse, mutect2, varscan2
- CGA | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100851666; called by muse, mutect2, varscan2
- CISD2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99913560; called by muse, mutect2, varscan2
- CIT | c.3860G>C p.R1287P | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55879516, COSV99948868; called by muse, mutect2, varscan2
- CLEC4F | c.1376A>T p.Q459L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99713619; called by muse, mutect2, varscan2
- CLGN | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100346453; called by muse, mutect2, varscan2
- CNTN1 | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100751121; called by muse, mutect2, varscan2
- CNTNAP2 | c.2645G>A p.W882* | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | catalogued as COSV100664095; called by muse, mutect2, varscan2
- COCH | c.364G>A p.E122K (on ENST00000216361 / NM_001347720.1; = p.E57K on NM_004086.3) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99363469; called by muse, mutect2, varscan2
- COL17A1 | c.3145A>G p.T1049A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV100793093, COSV100793372; called by muse, mutect2, varscan2
- COL6A6 | c.3716T>A p.V1239E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100650005; called by muse, mutect2, varscan2
- COL9A1 | c.2111C>G p.S704C | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100294294, COSV57881965; called by muse, mutect2, varscan2
- CPA3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936017; called by muse, mutect2, varscan2
- CRYZ | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV61718494; called by muse, mutect2, varscan2
- CSF2RB | c.2684A>C p.E895A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99453422; called by muse, mutect2, varscan2
- CSMD3 | c.11084G>C p.R3695P (on ENST00000297405 / NM_001363185.1; = p.R3526P on NM_052900.3) | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52118172, COSV52153817, COSV99828442; called by muse, mutect2, varscan2
- CSMD3 | c.6652+2T>A p.X2218_splice (on ENST00000297405 / NM_001363185.1; = p.X2114_splice on NM_052900.3) | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as rs758956904, COSV99828444; called by muse, mutect2
- CSMD3 | c.2334A>T p.K778N (on ENST00000297405 / NM_001363185.1; = p.K674N on NM_052900.3) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV52299290; called by muse, mutect2, varscan2
- CTNNA3 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65523055; called by muse, mutect2, varscan2
- CUL1 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100296522; called by muse, mutect2, varscan2
- DCUN1D1 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99489754; called by muse, mutect2, varscan2
- DHX35 | c.1264A>T p.M422L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV99326569; called by muse, mutect2, varscan2
- DLG4 | c.1490G>T p.R497L (on ENST00000399506 / NM_001321075.3; = p.R540L on NM_001365.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100263520; called by muse, mutect2, varscan2
- DMKN | c.897C>A p.D299E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as COSV100303333; called by muse, mutect2, varscan2
- DMP1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99218573; called by muse, mutect2, varscan2
- DNAH7 | c.917C>A p.A306E | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV100414386; called by muse, mutect2, varscan2
- DSC3 | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV100844558, COSV100844574; called by mutect2, varscan2
- DUOX2 | c.3515G>T p.G1172V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101199645; called by muse, mutect2, varscan2
- DVL3 | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99490448; called by muse, mutect2, varscan2
- DYSF | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99245300; called by muse, mutect2, varscan2
- EGFLAM | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100380016; called by muse, mutect2, varscan2
- ELMO2 | c.1489A>G p.S497G | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99281529; called by muse, mutect2, varscan2
- ENPP4 | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV100320261, COSV58088315; called by muse, mutect2, varscan2
- ENPP5 | c.470A>T p.Y157F | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100040371; called by muse, mutect2, varscan2
- EPHA5 | c.2776G>T p.D926Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99897255; called by muse, mutect2, varscan2
- EPHB6 | c.306G>C p.R102S | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235957, COSV101236004; called by muse, mutect2, varscan2
- ERCC6L2 | c.968T>C p.L323S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99998417; called by muse, mutect2, varscan2
- ERG | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as COSV99901437; called by muse, mutect2, varscan2
- ERICH3 | c.1341G>T p.E447D | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100443772; called by muse, mutect2, varscan2
- ERICH6 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901445; called by muse, mutect2, varscan2
- ERN2 | c.2691G>A p.M897I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs752294858, COSV99890921; called by muse, mutect2, varscan2
- F8 | c.3192G>C p.L1064F | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100811375; called by muse, mutect2, varscan2
- FAHD2B | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV99737964; called by muse, mutect2, varscan2
- FAM170A | c.958T>A p.C320S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.283); catalogued as COSV100088837; called by muse, mutect2, varscan2
- FCRL1 | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV100839742; called by muse, mutect2, varscan2
- FER1L6 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV101205595; called by muse, mutect2, varscan2
- FFAR1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981729343, COSV99322991; called by muse, mutect2, varscan2
- FGF10 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.511); catalogued as COSV52933571, COSV99240279; called by muse, mutect2
- FLT4 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as COSV99986311; called by muse, mutect2, varscan2
- FLVCR2 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | catalogued as rs778286255, COSV53163029, COSV99471131; called by muse, mutect2, varscan2
- FOXF1 | c.360C>A p.H120Q | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296418; called by muse, mutect2, varscan2
- FOXO3 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100669660; called by muse, varscan2
- FREM2 | c.2210A>T p.E737V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99747565; called by muse, mutect2, varscan2
- FSD1 | c.1012T>A p.F338I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99696651; called by muse, mutect2, varscan2
- GALNT17 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100352892, COSV100356424; called by muse, mutect2
- GGCX | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs150990432, COSV99289729; called by muse, mutect2, varscan2
- GNB1 | c.915A>G p.A305= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as rs779971509, COSV101060768; called by muse, mutect2, varscan2
- GOLGB1 | c.8892G>T p.R2964S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV100510470; called by muse, mutect2, varscan2
- GORASP2 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99304491; called by muse, mutect2, varscan2
- GPC5 | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100993149; called by muse, mutect2, varscan2
- H4C5 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV100747898; called by muse, mutect2, varscan2
- HECW1 | c.1599G>T p.R533S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.172); catalogued as rs1299103607, COSV101223043; called by muse, mutect2, varscan2
- HECW1 | c.2022C>G p.D674E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.897); catalogued as rs963677639, COSV101223045, COSV67840859; called by muse, mutect2, varscan2
- HECW1 | c.2296G>C p.A766P | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV101223049, COSV67822507, COSV67839582; called by muse, mutect2, varscan2
- HIVEP1 | c.28A>T p.R10* | Nonsense Mutation (SNP) | VAF 39/222 reads (18%) | catalogued as COSV101044940; called by muse, mutect2, varscan2
- HIVEP1 | c.3621G>C p.Q1207H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.976); catalogued as COSV101044941, COSV101045099; called by muse, mutect2, varscan2
- HLA-DQA1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV100567917; called by muse, mutect2, varscan2
- HLA-DRA | c.126C>G p.D42E | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100895051; called by muse, mutect2, varscan2
- HSPA4L | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99612724; called by muse, mutect2, varscan2
- HYDIN | c.12101G>A p.G4034D | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124975; called by muse, mutect2, varscan2
- IFNGR1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100880828; called by muse, varscan2
- IFNGR1 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100880830; called by muse, varscan2
- IFT81 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99655810; called by muse, mutect2, varscan2
- IGHV3-23 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.616); catalogued as rs782003672; called by muse, mutect2, varscan2
- IGLON5 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.055); catalogued as COSV99570517; called by muse, mutect2, varscan2
- IPP | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739432, COSV63432144, COSV63432196; called by muse, mutect2, varscan2
- IQCC | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs373839136; called by muse, mutect2, varscan2
- ITGA5 | c.1509del p.A504Pfs*12 | Frame Shift Del (DEL) | VAF 19/127 reads (15%) | catalogued as COSV53215735; called by mutect2, pindel, varscan2
- ITPRID1 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV100085927; called by muse, mutect2, varscan2
- IVNS1ABP | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.76); catalogued as COSV100832507; called by muse, mutect2, varscan2
- IWS1 | c.2197G>C p.V733L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99767078; called by muse, mutect2, varscan2
- KCMF1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101301235; called by muse, mutect2
- KCNMB1 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1442520418, COSV99210539; called by muse, mutect2, varscan2
- KDELR1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV99616065; called by muse, mutect2, varscan2
- KIAA0408 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100847512; called by muse, mutect2, varscan2
- KIF3A | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101109279; called by muse, mutect2, varscan2
- KIF5C | c.2273T>C p.I758T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs560626833, COSV101276109; called by muse, mutect2, varscan2
- KLF12 | c.60G>T p.M20I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV100888432; called by muse, mutect2, varscan2
- KRT73 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59839472; called by muse, mutect2, varscan2
- KRTAP10-11 | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100551505, COSV100552400; called by muse, mutect2, varscan2
- KSR2 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV56678095; called by muse, mutect2, varscan2
- LAMA2 | c.1177T>A p.C393S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117558, COSV101309304; called by muse, mutect2, varscan2
- LBH | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101257764; called by muse, mutect2, varscan2
- LMX1A | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV54221994; called by muse, mutect2
- LRP12 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV99407390; called by muse, mutect2, varscan2
- LRP1B | c.3154G>T p.G1052C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs927201996, COSV67287615; called by muse, mutect2, varscan2
- LTBP2 | c.3771T>A p.C1257* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99999924; called by muse, mutect2, varscan2
- MAST1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99262553; called by muse, mutect2, varscan2
- MBL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100906286; called by muse, mutect2
- MCM3AP | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99386618; called by muse, mutect2, varscan2
- MERTK | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99774273; called by muse, mutect2, varscan2
- MGA | c.1702G>T p.D568Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99579056; called by muse, mutect2
- MMGT1 | c.146C>G p.T49R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100018437; called by muse, mutect2, varscan2
- MORC1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99225438; called by muse, mutect2, varscan2
- MROH5 | c.3027G>C p.Q1009H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV101435949; called by muse, mutect2
- MSRA | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100412581; called by muse, mutect2, varscan2
- MTA2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1376997390, COSV99545147; called by muse, mutect2, varscan2
- MUC16 | c.43517T>C p.L14506P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV101109701; called by muse, mutect2, varscan2
- MUC16 | c.12976A>C p.T4326P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV101198830; called by muse, mutect2, varscan2
- MUC5B | c.7745C>A p.T2582N | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs1235562707, COSV101500132; called by muse, mutect2, varscan2
- MYH1 | c.1814A>T p.N605I | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99875271; called by muse, mutect2, varscan2
- MYH14 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99222131; called by muse, mutect2, varscan2
- MYH8 | c.651G>T p.G217= | Splice Region (SNP) | VAF 34/102 reads (33%) | catalogued as COSV101238310; called by muse, mutect2, varscan2
- MYO3A | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs368350598, COSV56327228; called by muse, mutect2, varscan2
- NEB | c.11548C>G p.P3850A | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99417476; called by muse, mutect2, varscan2
- NELL2 | c.1902G>C p.K634N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.084); catalogued as COSV100419036, COSV61570946; called by muse, mutect2, varscan2
- NFATC2 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101043561, COSV101043788; called by muse, mutect2, varscan2
- NLRP12 | c.1286G>T p.R429M | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100145010, COSV60743294; called by muse, mutect2, varscan2
- NOTCH4 | c.5921C>G p.P1974R | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV66680920; called by muse, mutect2, varscan2
- NR3C2 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as rs1553942816, COSV100678814; called by muse, mutect2
- NR3C2 | c.1484A>C p.Q495P | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100678817; called by muse, mutect2
- NT5C1B | c.929T>C p.I310T (on ENST00000359846 / NM_001199086.2; = p.I250T on NM_033253.4) | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1459254712, COSV100409895; called by muse, mutect2, varscan2
- NTRK3 | c.2204G>A p.R735H (on ENST00000360948 / NM_001012338.2; = p.R721H on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62297428; called by muse, mutect2, varscan2
- NUP107 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764034347, COSV57494858, COSV57495270; called by muse, mutect2, varscan2
- NUP155 | c.508C>T p.P170S (on ENST00000231498 / NM_153485.3; = p.P111S on NM_004298.4) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs771577745, COSV99192373; called by muse, mutect2, varscan2
- OCM2 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99990772; called by muse, mutect2, varscan2
- OR11H12 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs754908986, COSV101612470; called by muse, mutect2
- OR2M3 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV71758897; called by muse, mutect2, varscan2
- OR2T11 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.74); catalogued as COSV100424720, COSV100424729; called by muse, mutect2, varscan2
- OR2Z1 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.073); catalogued as COSV100136369; called by muse, mutect2, varscan2
- OR5I1 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100041287, COSV56886704; called by muse, mutect2, varscan2
- OR5L2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101004262; called by muse, mutect2, varscan2
- OR6C76 | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100094006; called by muse, mutect2, varscan2
- PACRG | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433501; called by muse, mutect2, varscan2
- PANX3 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV99421332; called by muse, mutect2, varscan2
- PAX1 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV101270246; called by muse, mutect2, varscan2
- PCDH11Y | c.1438C>A p.Q480K (on ENST00000400457 / NM_032973.2; = p.Q469K on NM_032971.3) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.309); catalogued as COSV53076643, COSV99290942; called by muse, mutect2, varscan2
- PCDH17 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931498; called by muse, mutect2, varscan2
- PCDH7 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs752040615, COSV100687790, COSV62343492; called by muse, mutect2, varscan2
- PCDHGB4 | c.2294T>A p.L765Q | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV99533658; called by muse, mutect2, varscan2
- PDE10A | c.1745T>C p.L582P | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604753; called by muse, mutect2, varscan2
- PDE2A | c.2469G>A p.A823= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as rs1263976937, COSV100557726; called by muse, mutect2
- PGBD2 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100251917; called by muse, mutect2, varscan2
- PIK3R1 | c.1872G>C p.W624C (on ENST00000521381 / NM_181523.3; = p.W354C on NM_181504.4) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141407; called by muse, mutect2, varscan2
- PIK3R4 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100768299, COSV100768563; called by muse, mutect2, varscan2
- PIKFYVE | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV52247519; called by muse, mutect2, varscan2
- PKHD1L1 | c.8137C>T p.L2713F | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs1249179453, COSV65737101; called by muse, mutect2, varscan2
- PLCD4 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101335810; called by muse, mutect2, varscan2
- PLEC | c.8965G>T p.G2989C (on ENST00000322810 / NM_201380.4; = p.G2879C on NM_000445.5) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100512122; called by muse, mutect2, varscan2
- PMFBP1 | c.1800C>A p.H600Q (on ENST00000537465; = p.H595Q on NM_031293.3) | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99400475; called by muse, mutect2, varscan2
- PRPS1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.453); catalogued as rs773719662, COSV100978848; called by muse, mutect2, varscan2
- PSMD14 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1456289952, COSV101293927; called by muse, mutect2, varscan2
- PTPRC | c.3420G>A p.M1140I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100722277; called by muse, mutect2, varscan2
- PUM1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs773969477, COSV99927682; called by muse, mutect2, varscan2
- PXDNL | c.2122G>T p.G708* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100682457; called by muse, mutect2, varscan2
- RAB3IP | c.313G>C p.D105H (on ENST00000550536 / NM_175623.4; = p.D89H on NM_022456.5) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.445); catalogued as COSV99923051, COSV99923680; called by muse, mutect2, varscan2
- RBL2 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV100043423, COSV100043717; called by muse, mutect2, varscan2
- RELN | c.2609G>A p.S870N | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.914); catalogued as rs772263839, COSV100632879; called by muse, mutect2, varscan2
- RGS4 | c.381G>C p.V127= | Splice Region (SNP) | VAF 60/248 reads (24%) | catalogued as COSV100905535, COSV63358170; called by muse, mutect2, varscan2
- ROBO3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs1344400264, COSV101184964; called by muse, mutect2, varscan2
- RPH3A | c.1990C>A p.R664S (on ENST00000389385 / NM_001143854.2; = p.R660S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV101231788; called by muse, mutect2, varscan2
- RSPO4 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54082480; called by muse, mutect2, varscan2
- SAMD7 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59417796, COSV99045850; called by muse, mutect2, varscan2
- SCN10A | c.2284C>A p.R762S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577819850, COSV101479291, COSV71861510; called by muse, mutect2, varscan2
- SCN2A | c.3969G>C p.M1323I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99330659; called by muse, mutect2, varscan2
- SCN4A | c.4343del p.R1448Lfs*2 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as CM080526, CM941271, CM951141; called by mutect2, pindel, varscan2
- SCN5A | c.1177T>C p.F393L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100347094; called by muse, mutect2, varscan2
- SET | c.817G>T p.D273Y (on ENST00000372692 / NM_001374326.1; = p.D260Y on NM_003011.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100433043; called by muse, mutect2, varscan2
- SLC17A6 | c.753C>G p.S251R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.167); catalogued as COSV99581039; called by muse, mutect2, varscan2
- SLC25A46 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV100582540; called by muse, mutect2, varscan2
- SLC33A1 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100848265; called by muse, mutect2, varscan2
- SLC5A8 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV101610518, COSV73310616; called by muse, mutect2, varscan2
- SMC6 | c.1714T>A p.Y572N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100704894; called by muse, mutect2, varscan2
- SORBS1 | c.1471G>T p.V491L (on ENST00000361941 / NM_001034954.2; = p.V281L on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99527631; called by muse, mutect2, varscan2
- SORCS3 | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99056365; called by muse, mutect2, varscan2
- SP4 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV56022660, COSV99754194; called by muse, mutect2, varscan2
- SPEF2 | c.4453A>G p.I1485V | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV100288835; called by muse, mutect2, varscan2
- SRRM4 | c.878C>A p.S293* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99938048; called by muse, mutect2, varscan2
- ST3GAL2 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | PolyPhen benign (0.145); catalogued as COSV100735624; called by muse, mutect2, varscan2
- STK31 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV100669227; called by muse, mutect2, varscan2
- STK31 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100669228; called by muse, mutect2, varscan2
- STRBP | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100724122; called by muse, mutect2, varscan2
- SYNPO2 | c.2978C>G p.S993* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100205148; called by muse, mutect2, varscan2
- TAAR6 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV99256547; called by muse, mutect2, varscan2
- TAF7L | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100774167; called by muse, mutect2, varscan2
- TCF4 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100609942; called by muse, mutect2, varscan2
- TENM2 | c.4474G>A p.E1492K (on ENST00000518659 / NM_001122679.2; = p.E1253K on NM_001080428.3) | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377115730; called by muse, mutect2, varscan2
- TFAP2D | c.727T>A p.C243S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV99145769; called by muse, mutect2, varscan2
- THBS1 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1451828826, COSV52954406, COSV52955370; called by muse, mutect2, varscan2
- TMEM202 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as COSV100499119; called by muse, mutect2, varscan2
- TMEM225 | c.233T>A p.F78Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100902770; called by muse, mutect2, varscan2
- TNFRSF10A | c.831G>A p.R277= | Splice Region (SNP) | VAF 48/204 reads (24%) | catalogued as COSV99646102; called by muse, mutect2, varscan2
- TNN | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV53436561; called by muse, mutect2, varscan2
- TNRC18 | c.5230G>T p.D1744Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101269588; called by muse, mutect2, varscan2
- TRIM15 | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100938797; called by muse, mutect2, varscan2
- TRIM61 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV100255963; called by muse, mutect2, varscan2
- TRPS1 | c.52G>C p.G18R (on ENST00000220888 / NM_001330599.2; = p.G31R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV55259068, COSV99629266; called by muse, mutect2, varscan2
- TTK | c.2261T>C p.I754T | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036120; called by muse, mutect2, varscan2
- TTN | c.83897G>T p.R27966L (on ENST00000591111; = p.R20542L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | PolyPhen possibly damaging (0.879); catalogued as COSV100600690; called by muse, mutect2, varscan2
- TTN | c.1841T>C p.I614T (on ENST00000591111; = p.I568T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | PolyPhen benign (0.015); catalogued as rs1417506492, COSV100600697; called by muse, mutect2, varscan2
- USH2A | c.14551C>A p.P4851T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as rs758804502, COSV100231359; called by muse, mutect2, varscan2
- VEZT | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1432632285, COSV99703581; called by muse, mutect2, varscan2
- VPS35L | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.783); catalogued as rs775946795, COSV99220057; called by muse, mutect2, varscan2
- VWA3B | c.3067C>G p.P1023A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV101345970; called by muse, mutect2, varscan2
- WDR7 | c.3628A>T p.T1210S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99588951; called by muse, mutect2, varscan2
- WDR72 | c.2366G>T p.S789I | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs752161762, COSV100854295; called by muse, mutect2, varscan2
- WSCD2 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs759121769, COSV54586779, COSV99774265; called by muse, mutect2, varscan2
- ZFHX3 | c.2722G>T p.G908C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99195977; called by muse, mutect2, varscan2
- ZFHX4 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.193); catalogued as COSV50478734, COSV99259381; called by muse, mutect2, varscan2
- ZFHX4 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV99259383; called by muse, mutect2, varscan2
- ZFHX4 | c.10410G>T p.L3470F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51480682; called by muse, mutect2, varscan2
- ZFP64 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.312); catalogued as rs992867295, COSV99402133; called by muse, mutect2, varscan2
- ZFYVE16 | c.3235G>T p.D1079Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100566285; called by muse, mutect2, varscan2
- ZNF180 | c.2071T>C p.C691R | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99659676; called by muse, mutect2, varscan2
- ZNF2 | c.659G>T p.G220V (on ENST00000611147 / NM_001291605.2; = p.G207V on NM_021088.4) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99728332; called by muse, mutect2, varscan2
- ZNF239 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.735); catalogued as COSV100021740; called by muse, mutect2, varscan2
- ZNF33A | c.1811G>A p.G604E (on ENST00000458705 / NM_006974.3; = p.G605E on NM_006954.2) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275616, COSV56724376; called by muse, mutect2, varscan2
- ZNF343 | c.1661G>T p.C554F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99601288; called by muse, mutect2, varscan2
- ZNF451 | c.1282A>G p.K428E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100674770; called by muse, mutect2, varscan2
- ZNF470 | c.585G>T p.M195I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100401137, COSV100401458; called by muse, mutect2, varscan2
- ZNF521 | c.1539C>A p.F513L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100833332, COSV64123101; called by muse, mutect2, varscan2
- ZNF644 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 54/225 reads (24%) | catalogued as COSV100494334; called by muse, mutect2, varscan2
- ZNF644 | c.3267T>A p.Y1089* | Nonsense Mutation (SNP) | VAF 52/221 reads (24%) | catalogued as COSV100494335; called by muse, mutect2, varscan2
- ZNF683 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100853684; called by muse, mutect2, varscan2
- ZNF691 | c.284G>A p.R95Q (on ENST00000372502; = p.R64Q on NM_015911.3) | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200892709, COSV100996066, COSV65289172; called by muse, mutect2, varscan2
- ZNF804A | c.3061G>T p.E1021* | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100166890; called by muse, mutect2, varscan2
- ATP13A2 | c.1856del p.P619Rfs*19 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2*
- BHLHE40 | c.641del p.G214Vfs*93 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- COL16A1 | c.1686dup p.V563Cfs*29 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- DHX36 | c.2560dup p.R854Kfs*19 | Frame Shift Ins (INS) | VAF 36/182 reads (20%) | called by mutect2, varscan2
- GALNT5 | c.600_616del p.S200Rfs*8 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- HERC2 | c.3631C>A p.R1211S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV3D-11 | c.56C>G p.T19S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MLLT10 | c.1311del p.G438Efs*21 | Frame Shift Del (DEL) | VAF 89/337 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 179/728 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PRMT8 | c.1027del p.E343Kfs*18 | Frame Shift Del (DEL) | VAF 53/247 reads (21%) | called by mutect2, pindel, varscan2
- SLC9A2 | c.1936del p.E646Kfs*9 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.5176A>G p.K1726E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF98 | c.1068del p.K357Rfs*98 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel*
- ABI3 | c.894G>A p.G298= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV99865353; called by muse, mutect2, varscan2
- ACADSB | c.444A>G p.T148= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100715111, COSV62550840; called by muse, mutect2, varscan2
- ADGRL2 | c.2160C>T p.Y720= (on ENST00000370717 / NM_001366005.1; = p.Y707= on NM_012302.4) | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs1225584292, COSV99587701; called by muse, mutect2, varscan2
- AGTR1 | c.342T>C p.A114= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as COSV100836969; called by muse, mutect2, varscan2
- ARAP1 | c.1161G>A p.K387= (on ENST00000393609 / NM_001040118.2; = p.K142= on NM_015242.4) | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV100501673; called by muse, mutect2, varscan2
- ARSL | c.129G>C p.L43= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101140444; called by muse, mutect2, varscan2
- ASB18 | c.90G>A p.E30= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV101293585; called by muse, mutect2, varscan2
- ASMTL | c.1485C>A p.P495= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs377056125, COSV101187718; called by muse, mutect2, varscan2
- BRWD3 | c.3751C>T p.L1251= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100955812, COSV64754236; called by muse, mutect2, varscan2
- CBLN2 | c.471C>A p.T157= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs781570135, COSV54050896, COSV54052702; called by muse, mutect2, varscan2
- CDH10 | c.1746G>T p.L582= | Silent (SNP) | VAF 92/145 reads (63%) | catalogued as COSV52586448; called by muse, mutect2, varscan2
- CELF3 | c.510G>A p.V170= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99310132; called by muse, mutect2, varscan2
- CGA | c.147A>T p.I49= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV100851667; called by muse, mutect2, varscan2
- CHRNG | c.498T>A p.L166= | Silent (SNP) | VAF 45/194 reads (23%) | catalogued as COSV101263905; called by muse, mutect2, varscan2
- CIT | c.3861G>T p.R1287= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV99948866; called by muse, mutect2, varscan2
- CPVL | c.234C>A p.L78= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99605503; called by muse, mutect2
- CUX2 | c.2355C>T p.F785= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV55637281; called by muse, mutect2, varscan2
- CWC22 | c.636C>T p.T212= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99844101; called by muse, mutect2, varscan2
- DAPK1 | c.4269C>T p.S1423= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100801347; called by muse, mutect2, varscan2
- DES | c.936C>T p.D312= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs769213907, COSV100900323; called by muse, mutect2, varscan2
- DIXDC1 | c.180C>T p.I60= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs374969048; called by muse, mutect2, varscan2
- DLST | c.36C>T p.F12= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1384565108, COSV99471861; called by muse, mutect2, varscan2
- DMBT1 | c.354A>G p.L118= | Silent (SNP) | VAF 71/355 reads (20%) | catalogued as COSV100352473; called by muse, mutect2, varscan2
- DNAJC9 | c.552A>G p.Q184= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV99654549; called by muse, mutect2, varscan2
- EPS8 | c.123A>T p.A41= | Silent (SNP) | VAF 69/271 reads (25%) | catalogued as COSV99842813; called by muse, mutect2, varscan2
- FAT2 | c.10951C>T p.L3651= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1006488938, COSV99942061; called by muse, mutect2, varscan2
- FEV | c.417C>A p.P139= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs750483793, COSV99837872; called by muse, varscan2
- GFRA2 | c.1020G>A p.R340= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100151524; called by muse, mutect2, varscan2
- GOLGB1 | c.5535C>G p.L1845= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV100510473, COSV104415563; called by muse, mutect2, varscan2
- GPC2 | c.1599T>C p.D533= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99444444; called by muse, mutect2, varscan2
- GRM1 | c.3273C>G p.S1091= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV51173795, COSV99264849; called by muse, mutect2, varscan2
- IGKV2D-30 | c.192G>A p.R64= | Silent (SNP) | VAF 52/294 reads (18%) | called by muse, mutect2, varscan2
- INPP5B | c.141C>A p.G47= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV100886106; called by muse, mutect2, varscan2
- INSRR | c.501C>T p.I167= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs369512155; called by muse, mutect2, varscan2
- INTS4 | c.162A>G p.Q54= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV101417151; called by muse, mutect2, varscan2
- ITIH1 | c.291C>A p.I97= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV56255003, COSV56259316, COSV99835058; called by muse, mutect2, varscan2
- KANSL2 | c.360C>T p.S120= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100770852; called by muse, mutect2, varscan2
- KIF16B | c.2016A>G p.L672= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as COSV100733963; called by muse, mutect2, varscan2
- LHX8 | c.687G>T p.R229= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99633306; called by muse, mutect2, varscan2
- LRRC56 | c.375C>T p.R125= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99529723; called by muse, mutect2, varscan2
- MAGEC1 | c.2418C>A p.A806= | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as COSV99595195; called by muse, mutect2, varscan2
- MTMR10 | c.654T>C p.T218= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100075995; called by muse, mutect2
- MTRR | c.1926T>C p.V642= (on ENST00000264668; = p.V615= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV99241414; called by muse, mutect2, varscan2
- MUC17 | c.2628G>T p.L876= | Silent (SNP) | VAF 134/532 reads (25%) | catalogued as rs189799131, COSV100072275; called by muse, mutect2, varscan2
- NLRP4 | c.1251C>T p.D417= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs376218682, COSV56714165; called by muse, mutect2, varscan2
- NOTCH2 | c.5730C>T p.G1910= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99863211; called by muse, mutect2, varscan2
- OLFML2B | c.1579C>A p.R527= | Silent (SNP) | VAF 53/242 reads (22%) | catalogued as COSV99668185; called by muse, mutect2, varscan2
- OR5D13 | c.126G>T p.V42= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as rs772340587, COSV100686773; called by muse, mutect2, varscan2
- OR5R1 | c.810A>T p.T270= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV100393328; called by muse, mutect2, varscan2
- OR7G1 | c.321T>C p.F107= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as COSV99528442; called by muse, mutect2, varscan2
- PARP1 | c.2529C>G p.G843= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs148631906, COSV100828818, COSV100828853; called by muse, mutect2, varscan2
- PCDH11X | c.1191A>G p.T397= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as rs1291514177, COSV100009681; called by muse, mutect2
- PCDH7 | c.1668G>C p.T556= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100687791; called by muse, mutect2, varscan2
- PCDHA13 | c.2283G>T p.G761= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99165310; called by muse, mutect2, varscan2
- PCDHGA12 | c.1854G>C p.S618= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV99338818; called by muse, mutect2, varscan2
- PDE10A | c.2061G>A p.L687= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs1052174822, COSV100604751; called by muse, mutect2, varscan2
- PDZK1IP1 | c.114C>T p.A38= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs779800928, COSV99595565; called by muse, mutect2
- PHF14 | c.1540C>T p.L514= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as COSV101301783; called by muse, mutect2, varscan2
- PKP4 | c.2724C>T p.L908= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs878929660, COSV100733753; called by muse, mutect2, varscan2
- PLEKHG6 | c.906C>G p.L302= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99164125; called by muse, mutect2, varscan2
- POTEE | c.2517G>T p.V839= | Silent (SNP) | VAF 39/257 reads (15%) | catalogued as COSV100387324; called by muse, mutect2, varscan2
- PTPRR | c.384G>C p.L128= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs751707569, COSV99316692; called by muse, mutect2, varscan2
- RBM12B | c.888C>T p.D296= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs773393329, COSV101197130; called by muse, mutect2, varscan2
- RGS7BP | c.555C>A p.P185= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100470527; called by muse, mutect2, varscan2
- RPS6KA2 | c.1149G>A p.L383= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV99690420; called by muse, mutect2, varscan2
- SACS | c.8508C>G p.V2836= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV101207254; called by muse, mutect2, varscan2
- SHANK1 | c.870G>C p.V290= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV99520561; called by muse, mutect2, varscan2
- SHF | c.1173C>T p.S391= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs763252624, COSV99334325; called by muse, mutect2, varscan2
- SYT1 | c.39G>A p.P13= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs374005304; called by muse, mutect2, varscan2
- SYT4 | c.45C>A p.P15= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99673509; called by muse, mutect2, varscan2
- TAS2R20 | c.741A>T p.I247= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV101114403; called by muse, mutect2, varscan2
- TASOR2 | c.7032G>A p.K2344= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV100050123; called by muse, mutect2, varscan2
- TMEM202 | c.204C>A p.L68= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100499118; called by muse, mutect2, varscan2
- TOPORS | c.162G>C p.A54= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100598260; called by muse, mutect2, varscan2
- TRIO | c.2538C>A p.I846= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV100710064; called by muse, mutect2
- TTN | c.81291T>C p.D27097= (on ENST00000591111; = p.D19673= on NM_003319.4) | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV100600693; called by muse, mutect2, varscan2
- TUBA3C | c.525C>A p.P175= | Silent (SNP) | VAF 50/183 reads (27%) | catalogued as rs370537577, COSV101262763; called by muse, mutect2, varscan2
- UBE2O | c.1557C>T p.S519= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV100084300; called by muse, mutect2, varscan2
- UBR4 | c.12663G>T p.L4221= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100920591; called by muse, mutect2, varscan2
- UQCC1 | c.705C>T p.F235= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100568391; called by muse, mutect2, varscan2
- USH2A | c.4206T>C p.L1402= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV100231364; called by muse, mutect2, varscan2
- XIRP2 | c.4914G>A p.V1638= (on ENST00000628543; = p.V1813= on NM_152381.6) | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs938825834, COSV99740181; called by muse, mutect2, varscan2
- XPO4 | c.2142A>G p.R714= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99688258; called by muse, mutect2, varscan2
- ZFYVE1 | c.2178G>A p.K726= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV100606626; called by muse, mutect2, varscan2
- ZNF638 | c.1017G>A p.S339= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs749560871, COSV52485044; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821924 A>G | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- C7orf66 | n.384C>T | RNA (SNP) | VAF 19/139 reads (14%) | catalogued as rs145742437; called by muse, mutect2, varscan2
- DPF3 | c.871+3024G>A | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as COSV63500099; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22366C>A | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101050935; called by muse, mutect2, varscan2
- NACA | c.71-4589G>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100771170; called by muse, mutect2, varscan2
- PRB1 | c.101-534C>T | Intron (SNP) | VAF 41/450 reads (9%) | catalogued as rs530566644, COSV53707150; called by muse, mutect2
